Somatic mutation profile of tumor specimen MBCProject_5809_T1_WES (aliquot MBCProject_5809_T1_WES_1) from CMI case MBCProject_5809, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 57.9 years (21,132 days).
Specimen MBCProject_5809_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0f3c77a-f06f-4172-97ec-c69416884107.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_5809_SALIVA (Saliva), aliquot MBCProject_5809_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e75a8ac1-3564-4700-81e2-48320de086a1

The open-access MAF lists 83 somatic variants for this specimen: 52 protein-altering or splice-affecting, 19 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 19, Nonsense Mutation 8, Intron 6, 3'UTR 3, Frame Shift Del 2, 5'Flank 2, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1637A>G p.Q546R | Missense Mutation (SNP) | VAF 28/114 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 33/348 reads (9%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- APOA5 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 33/660 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as CM119840; called by muse, mutect2
- ATF7IP2 | c.1032G>T p.L344F | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV61094902; called by muse, mutect2
- CLCN4 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101073949; called by muse, mutect2
- FAM71E2 | c.2303G>C p.G768A | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.011); catalogued as COSV58483169; called by muse, mutect2, varscan2
- GRIP1 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54033166; called by muse, mutect2
- HOXA1 | c.853A>T p.K285* | Nonsense Mutation (SNP) | VAF 50/670 reads (7%) | catalogued as COSV58031277; called by muse, mutect2
- KDM4B | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50219409, COSV99346196; called by muse, mutect2
- MTUS1 | c.1444T>G p.S482A | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.173); catalogued as rs1303597883; called by muse, mutect2
- PCDH19 | c.3080C>A p.A1027D (on ENST00000373034 / NM_001184880.2; = p.A979D on NM_020766.3) | Missense Mutation (SNP) | VAF 12/301 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV55273668; called by muse, mutect2
- RECQL4 | c.3005C>T p.S1002F | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.622); catalogued as rs1320482850; called by muse, mutect2
- RNF157 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 10/213 reads (5%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs1245133315, COSV53941457; called by muse, mutect2
- TENT5B | c.1171C>A p.R391S | Missense Mutation (SNP) | VAF 15/162 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV56693067; called by muse, mutect2, varscan2
- ABCA12 | c.1978C>T p.Q660* (on ENST00000272895 / NM_173076.3; = p.Q342* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- ADGRF4 | c.953G>T p.G318V | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by mutect2, varscan2
- AHNAK2 | c.8794G>T p.V2932L | Missense Mutation (SNP) | VAF 58/485 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ANKEF1 | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 11/253 reads (4%) | SIFT tolerated (0.93); PolyPhen benign (0.005); called by muse, mutect2
- BAG4 | c.771G>A p.W257* | Nonsense Mutation (SNP) | VAF 43/418 reads (10%) | called by muse, mutect2, varscan2
- CARMIL3 | c.3805C>T p.Q1269* | Nonsense Mutation (SNP) | VAF 18/280 reads (6%) | called by muse, mutect2
- CCNF | c.1238A>G p.Y413C | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCNY | c.932A>T p.D311V | Missense Mutation (SNP) | VAF 19/324 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CNTLN | c.2447C>G p.S816C | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.051); called by muse, mutect2
- CRACD | c.2996A>T p.E999V | Missense Mutation (SNP) | VAF 12/291 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2
- DHDH | c.167G>A p.G56D | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- DNAH9 | c.671G>T p.W224L | Missense Mutation (SNP) | VAF 11/202 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- DNAJB14 | c.89T>C p.F30S | Missense Mutation (SNP) | VAF 47/774 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2
- EDC4 | c.3517C>T p.Q1173* | Nonsense Mutation (SNP) | VAF 14/250 reads (6%) | called by muse, mutect2
- EXO1 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.255); called by muse, varscan2
- EXOC2 | c.1793_1796del p.I598Rfs*3 | Frame Shift Del (DEL) | VAF 6/66 reads (9%) | called by mutect2, pindel
- FAM53B | c.331A>G p.K111E | Missense Mutation (SNP) | VAF 11/212 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GALNT8 | c.343C>A p.Q115K | Missense Mutation (SNP) | VAF 14/323 reads (4%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2
- GLRX5 | c.267C>A p.N89K | Missense Mutation (SNP) | VAF 85/350 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- GTF2H3 | c.655C>T p.Q219* | Nonsense Mutation (SNP) | VAF 21/346 reads (6%) | called by muse, mutect2
- HNRNPH3 | c.725T>C p.V242A | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.055); called by muse, mutect2
- MAP3K3 | c.116C>G p.S39* | Nonsense Mutation (SNP) | VAF 8/119 reads (7%) | called by muse, mutect2
- MLKL | c.1307A>C p.D436A | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR10H1 | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- PKM | c.1521T>G p.D507E | Missense Mutation (SNP) | VAF 45/460 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.419); called by muse, mutect2
- PPIE | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- PPP1CA | c.96G>C p.E32D | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.02); called by muse, mutect2
- PRR14 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.068); called by muse, mutect2
- PTEN | c.956_965del p.T319Kfs*22 | Frame Shift Del (DEL) | VAF 12/90 reads (13%) | called by mutect2, pindel
- RBMS3 | c.888+2T>C p.X296_splice | Splice Site (SNP) | VAF 14/196 reads (7%) | called by muse, mutect2
- REST | c.1484C>G p.S495* | Nonsense Mutation (SNP) | VAF 16/226 reads (7%) | called by muse, mutect2
- RNF40 | c.2200G>C p.E734Q | Missense Mutation (SNP) | VAF 27/470 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- RSPH6A | c.1020C>A p.H340Q | Missense Mutation (SNP) | VAF 14/294 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2
- TBX5 | c.305T>C p.L102P | Missense Mutation (SNP) | VAF 19/484 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMC6 | c.91C>T p.H31Y | Missense Mutation (SNP) | VAF 23/386 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- TMOD3 | c.772A>C p.K258Q | Missense Mutation (SNP) | VAF 16/203 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2
- TMPRSS15 | c.1969C>T p.P657S | Missense Mutation (SNP) | VAF 15/224 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.209); called by muse, mutect2
- ULK1 | c.521G>A p.S174N | Missense Mutation (SNP) | VAF 36/486 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2
- ALPP | c.958C>T p.L320= | Silent (SNP) | VAF 33/792 reads (4%) | called by muse, mutect2
- BRWD3 | c.1890A>C p.V630= | Silent (SNP) | VAF 15/245 reads (6%) | called by muse, mutect2
- CCDC66 | c.1185T>C p.S395= (on ENST00000394672 / NM_001353147.1; = p.S361= on NM_001012506.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 16/212 reads (8%) | called by muse, mutect2
- CHRNA2 | c.1561C>T p.L521= | Silent (SNP) | VAF 18/218 reads (8%) | catalogued as rs1427296744, COSV99532587; called by muse, mutect2
- DGKQ | c.1491G>A p.P497= | Silent (SNP) | VAF 19/199 reads (10%) | catalogued as rs749949279, COSV56619818; called by muse, mutect2
- DYNC1I1 | c.1530T>C p.F510= | Silent (SNP) | VAF 10/213 reads (5%) | catalogued as rs1395029467; called by muse, mutect2
- ECI1 | c.7C>T p.L3= | Silent (SNP) | VAF 25/463 reads (5%) | catalogued as rs900211278; called by muse, mutect2
- EVC2 | c.1083C>T p.N361= | Silent (SNP) | VAF 36/307 reads (12%) | catalogued as rs142231129; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- IL12B | c.948C>T p.S316= | Silent (SNP) | VAF 32/512 reads (6%) | catalogued as rs756372086; called by muse, mutect2
- KIAA2013 | c.576T>C p.F192= | Silent (SNP) | VAF 20/306 reads (7%) | catalogued as rs1421035689; called by muse, mutect2
- LRP8 | c.1881C>T p.F627= | Silent (SNP) | VAF 16/158 reads (10%) | called by muse, mutect2
- MATN4 | c.423C>T p.V141= | Silent (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2
- MRFAP1L1 | c.117C>T p.I39= | Silent (SNP) | VAF 20/382 reads (5%) | called by muse, mutect2
- NDRG2 | c.1083G>A p.G361= (on ENST00000298687 / NM_001354570.1; = p.G347= on NM_016250.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 29/276 reads (11%) | called by muse, mutect2, varscan2
- NEK8 | c.1152C>T p.F384= | Silent (SNP) | VAF 28/474 reads (6%) | catalogued as COSV52044991; called by muse, mutect2
- RFX6 | c.342G>T p.V114= | Silent (SNP) | VAF 28/408 reads (7%) | called by muse, mutect2
- THBS1 | c.1260A>G p.T420= | Silent (SNP) | VAF 9/184 reads (5%) | catalogued as rs911635624; called by muse, mutect2
- TNFAIP8L1 | c.453C>T p.A151= | Silent (SNP) | VAF 22/198 reads (11%) | catalogued as rs772982234; called by muse, mutect2, varscan2
- ZAN | c.150C>T p.L50= | Silent (SNP) | VAF 43/264 reads (16%) | called by muse, mutect2, varscan2
- AGBL1 | c.970-114G>T | Intron (SNP) | VAF 9/124 reads (7%) | called by muse, mutect2
- CLRN1 | c.*849G>T | 3'UTR (SNP) | VAF 16/151 reads (11%) | called by muse, mutect2, varscan2
- COL4A1 | c.615+54G>T | Intron (SNP) | VAF 14/190 reads (7%) | called by muse, mutect2
- ETFA | c.883-1927A>G | Intron (SNP) | VAF 20/211 reads (9%) | catalogued as rs1418197652; called by muse, mutect2
- NACA | c.70+3822T>A | Intron (SNP) | VAF 11/231 reads (5%) | called by muse, mutect2
- NPEPL1 | chr20:58691787 G>C | 5'Flank (SNP) | VAF 24/370 reads (6%) | catalogued as rs1271739988; called by muse, mutect2
- PIN1 | c.58+32_58+61del | Intron (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel
- SLC9A5 | c.*71C>A | 3'UTR (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- SNORD116-14 | n.21A>G | RNA (SNP) | VAF 10/220 reads (5%) | called by muse, mutect2
- TEDC1 | chr14:105491063 G>C | 5'Flank (SNP) | VAF 78/774 reads (10%) | called by muse, mutect2, varscan2
- TNRC18 | c.*550A>G | 3'UTR (SNP) | VAF 9/156 reads (6%) | called by muse, mutect2
- TTN | c.10360+3051A>T | Intron (SNP) | VAF 12/242 reads (5%) | called by muse, mutect2
